Somatic mutation profile of tumor specimen TCGA-FD-A3B6-01A (aliquot TCGA-FD-A3B6-01A-21D-A20D-08) from TCGA case TCGA-FD-A3B6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 75.4 years (27,541 days).
Specimen TCGA-FD-A3B6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bde0403c-04f2-4d91-903a-1f77237a48ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3B6-10A (Blood Derived Normal), aliquot TCGA-FD-A3B6-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a84ce5a0-4411-460f-94bc-adcd2b2dcec6

The open-access MAF lists 296 somatic variants for this specimen: 226 protein-altering or splice-affecting, 66 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 192, Silent 66, Nonsense Mutation 23, Splice Site 4, Frame Shift Del 4, Intron 2, Nonstop Mutation 1, 3'UTR 1, Frame Shift Ins 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNM1L | c.346_347del p.E116Kfs*6 | Frame Shift Del (DEL) | VAF 34/89 reads (38%) | catalogued as rs879255687; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ERBB3 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 50/265 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519891, COSV57247504, COSV57260861, COSV57263527; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 19/90 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: drug response / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1700C>T p.S567L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853292, CM145432, CM900193, COSV57298146, COSV57300603; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 25/99 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC3 | c.3312C>G p.I1104M | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs774293390, COSV53326894; called by muse, mutect2, varscan2
- ABCC9 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 101/184 reads (55%) | SIFT tolerated (0.83); PolyPhen benign (0.103); catalogued as COSV53981438; called by muse, mutect2, varscan2
- ABCD3 | c.287G>C p.R96P | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59866839, COSV59867332; called by muse, mutect2, varscan2
- ACACB | c.6952G>C p.E2318Q | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV58129008, COSV58140265; called by muse, mutect2, varscan2
- ACOT8 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 61/445 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.147); catalogued as COSV54170011; called by muse, mutect2, varscan2
- ADAMTS20 | c.5639C>T p.S1880L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV67136798; called by muse, varscan2
- ADARB2 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV67232530; called by muse, mutect2, varscan2
- ADCY2 | c.2266C>T p.R756W | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs1310622653, COSV57890905; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.985G>T p.V329F | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs376664570, COSV58445686; called by muse, mutect2, varscan2
- ALAS1 | c.41T>G p.V14G | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV59629172; called by muse, varscan2
- ALG9 | c.1669G>C p.E557Q (on ENST00000614444 / NM_001352418.1; = p.E564Q on NM_024740.2) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV67644921, COSV67645264; called by muse, mutect2, varscan2
- ANK1 | c.2773T>A p.S925T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV55891106; called by muse, mutect2, varscan2
- ANK2 | c.5626G>A p.E1876K | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.385); catalogued as rs1554553071, COSV52179553; ClinVar: uncertain significance; called by muse, varscan2
- ANKRD34B | c.1384G>T p.D462Y | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV58613564, COSV58614353; called by muse, mutect2, varscan2
- ATP2A3 | c.3024G>C p.W1008C | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV59233526; called by muse, mutect2, varscan2
- BARD1 | c.1816C>G p.H606D | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53615398; called by muse, mutect2, varscan2
- BTAF1 | c.2716C>A p.Q906K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV56437080, COSV56437628; called by muse, mutect2, varscan2
- C4orf51 | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV71264554; called by muse, mutect2, varscan2
- CACNA1C | c.1827G>C p.K609N | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.673); catalogued as COSV59755600; called by muse, mutect2
- CAMTA2 | c.2938G>C p.E980Q | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as rs762884736, COSV52778749; called by muse, mutect2, varscan2
- CBLB | c.2824G>C p.E942Q | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT tolerated, low confidence (0.7); PolyPhen probably damaging (0.996); catalogued as COSV51433596; called by muse, mutect2
- CCDC81 | c.1825G>A p.D609N (on ENST00000445632 / NM_001156474.2; = p.D519N on NM_021827.4) | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.948); catalogued as COSV53580416; called by muse, mutect2, varscan2
- CCDC92 | c.801del p.I268Sfs*40 | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | catalogued as rs773752200; called by mutect2, pindel, varscan2
- CCT6A | c.913C>G p.L305V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV51907178; called by muse, mutect2, varscan2
- CDH19 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV50969938; called by muse, mutect2, varscan2
- CDH19 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.262); catalogued as rs1185553868, COSV50969981; called by muse, varscan2
- CFAP52 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as COSV55347873; called by muse, mutect2, varscan2
- CHD9 | c.3955C>T p.R1319* | Nonsense Mutation (SNP) | VAF 34/237 reads (14%) | catalogued as COSV99529447; called by muse, mutect2, varscan2
- CHFR | c.1138G>C p.D380H (on ENST00000432561 / NM_001161345.1; = p.D339H on NM_018223.2) | Missense Mutation (SNP) | VAF 88/340 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57176968; called by muse, mutect2, varscan2
- COL11A1 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1462597589, COSV100615721, COSV62191823; called by muse, mutect2, varscan2
- COL13A1 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 38/580 reads (7%) | catalogued as COSV62567160; called by muse, mutect2
- COL21A1 | c.1537G>C p.D513H | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV55174525; called by muse, mutect2, varscan2
- CR2 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100889655, COSV65509043; called by muse, mutect2, varscan2
- CRB1 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV66346027; called by muse, mutect2, varscan2
- CROT | c.1345C>T p.H449Y | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1223749609, COSV58976196; called by muse, mutect2, varscan2
- CRYBG1 | c.4537G>C p.D1513H | Missense Mutation (SNP) | VAF 70/392 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.605); catalogued as COSV64813825; called by muse, mutect2, varscan2
- CST1 | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59055994, COSV59056019; called by muse, mutect2, varscan2
- CYB5D2 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV56801804; called by muse, mutect2, varscan2
- DAAM1 | c.3128G>T p.G1043V | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62838709; called by muse, mutect2, varscan2
- DALRD3 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.207); catalogued as rs781227318, COSV58246130, COSV58247362; called by muse, mutect2
- DBF4 | c.698A>G p.Y233C | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55998256; called by muse, mutect2, varscan2
- DCLK2 | c.1013C>G p.S338C | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as COSV56209557; called by muse, mutect2, varscan2
- DGKB | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs184790928, COSV51808202; called by muse, mutect2, varscan2
- DGKI | c.2629G>A p.A877T | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV55967856; called by muse, mutect2, varscan2
- DIDO1 | c.6007G>C p.E2003Q | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.62); catalogued as rs1279695803, COSV56630973, COSV99826785; called by muse, mutect2, varscan2
- DLGAP5 | c.2182C>G p.L728V | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.112); catalogued as rs1298117209, COSV55964747; called by muse, mutect2, varscan2
- DNAH2 | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1209932487, COSV50013885; called by muse, mutect2, varscan2
- DNAH2 | c.4179C>G p.L1393= | Splice Region (SNP) | VAF 18/131 reads (14%) | catalogued as COSV66723932; called by muse, mutect2, varscan2
- DNAJB4 | c.718C>A p.H240N | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV66131996; called by muse, mutect2, varscan2
- EDC4 | c.1359C>A p.F453L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV62767376; called by muse, mutect2, varscan2
- EFR3A | c.1440G>T p.L480F | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.288); catalogued as COSV54460831; called by muse, mutect2, varscan2
- ENTHD1 | c.1526C>G p.S509C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV57323573; called by muse, mutect2, varscan2
- EPG5 | c.2407T>C p.Y803H | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs762353654, COSV56354177; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ETS1 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs766647712, COSV60092154, COSV60096096; called by muse, mutect2, varscan2
- EXOSC9 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.473); catalogued as COSV54666698; called by muse, mutect2, varscan2
- F5 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV63126602; called by muse, mutect2, varscan2
- FAAP20 | c.538T>C p.W180R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66032213; called by muse, mutect2, varscan2
- FAIM | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV58159076; called by muse, mutect2
- FAM234A | c.56G>C p.R19T | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.074); catalogued as COSV56997110; called by muse, mutect2, varscan2
- FAM234A | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 68/431 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.361); catalogued as COSV56997143; called by muse, varscan2
- FGD4 | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); catalogued as rs766829554, COSV56787818; called by muse, mutect2, varscan2
- FRY | c.8035G>A p.D2679N | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs781431979, COSV66570062; called by muse, mutect2, varscan2
- GCN1 | c.6067G>A p.E2023K | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.069); catalogued as COSV56112898; called by muse, mutect2, varscan2
- GLB1L3 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758676879, COSV66282796; called by muse, mutect2, varscan2
- GLIPR1 | c.294G>C p.E98D | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56992167; called by muse, mutect2, varscan2
- GLIS3 | c.1558G>C p.D520H | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV60923301, COSV60933476; called by muse, mutect2, varscan2
- GNAT1 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV50033658; called by muse, mutect2, varscan2
- GNB3 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs782659190, COSV51835491, COSV99301569; called by muse, mutect2, varscan2
- GNPAT | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.239); catalogued as COSV64154029; called by muse, mutect2
- GPSM3 | c.410A>G p.E137G | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV66682919; called by muse, mutect2, varscan2
- GRIN2A | c.2547C>A p.F849L | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.748); catalogued as COSV58026969, COSV58050136; called by muse, mutect2, varscan2
- GTF2H1 | c.645G>C p.M215I | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.544); catalogued as COSV56379709, COSV56380037; called by muse, mutect2, varscan2
- GTF3C1 | c.1281G>C p.K427N | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62243840; called by muse, mutect2, varscan2
- GTPBP6 | c.1415G>T p.G472V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58205520; called by muse, mutect2, varscan2
- HDAC10 | c.1634C>G p.S545C | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs777318498, COSV50569706; called by muse, mutect2, varscan2
- HSPA1L | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.099); catalogued as COSV65150451, COSV65150873, COSV65151044; called by muse, mutect2, varscan2
- HUS1 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 42/205 reads (20%) | catalogued as rs1446254392; called by muse, mutect2
- HYDIN | c.5614G>A p.E1872K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59265995; called by muse, mutect2, varscan2
- IFI44L | c.934C>G p.L312V | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60728863; called by muse, mutect2, varscan2
- IFNA16 | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 208/544 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as rs1343947830, COSV66510174, COSV66510467; called by muse, mutect2, varscan2
- IFT88 | c.1465G>C p.D489H (on ENST00000319980 / NM_001318493.2; = p.D480H on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60675967; called by muse, mutect2
- IPCEF1 | c.608C>A p.T203K | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV54549210; called by muse, mutect2
- ITGA11 | c.601G>T p.V201F | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59880715; called by muse, mutect2, varscan2
- ITGA2 | c.3107C>T p.S1036F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.12); catalogued as COSV56864901; called by muse, mutect2, varscan2
- ITK | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.294); catalogued as COSV70061389; called by muse, mutect2, varscan2
- KCNH4 | c.2386C>T p.H796Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV52920213; called by muse, varscan2
- KCNK1 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs149408317; called by muse, mutect2, varscan2
- KIF26B | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.098); catalogued as rs762608921, COSV69469558; called by muse, mutect2, varscan2
- KMT5B | c.47G>C p.R16T | Missense Mutation (SNP) | VAF 67/394 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV58568790; called by muse, mutect2, varscan2
- KYAT3 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV53104400; called by muse, mutect2, varscan2
- L1CAM | c.2504C>T p.P835L | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.432); catalogued as rs781912495, COSV62829532; called by muse, mutect2, varscan2
- LAMA2 | c.2078G>A p.G693E | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as COSV70352872; called by muse, mutect2, varscan2
- LCT | c.3787G>A p.E1263K | Missense Mutation (SNP) | VAF 90/174 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51555035; called by muse, mutect2, varscan2
- LRRC31 | c.986C>A p.S329* | Nonsense Mutation (SNP) | VAF 30/146 reads (21%) | catalogued as COSV99246590; called by muse, mutect2, varscan2
- LRRC41 | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV58441614; called by muse, mutect2, varscan2
- LRRTM3 | c.680G>C p.R227T | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63670006; called by muse, mutect2, varscan2
- MAP1B | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57103925; called by muse, mutect2, varscan2
- MAPK4 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV68543289; called by muse, mutect2, varscan2
- MARK1 | c.862C>A p.L288M | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65069757, COSV65070227; called by muse, mutect2, varscan2
- MIER2 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.381); catalogued as COSV53397573; called by muse, mutect2, varscan2
- MRPL50 | c.166C>G p.R56G | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV66406319; called by muse, mutect2, varscan2
- MTERF1 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.068); catalogued as COSV61098916; called by muse, mutect2, varscan2
- MTMR10 | c.2038C>T p.H680Y | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.808); catalogued as COSV58729400; called by muse, mutect2, varscan2
- MYCBP2 | c.3064C>A p.Q1022K (on ENST00000357337; = p.Q1060K on NM_015057.5) | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV62033076; called by muse, mutect2
- MYF5 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 19/92 reads (21%) | catalogued as COSV57354930; called by muse, mutect2, varscan2
- MYO1C | c.497G>A p.R166H (on ENST00000648651 / NM_001080779.2; = p.R131H on NM_033375.5) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs748056997, COSV63000299; called by muse, mutect2, varscan2
- NAV2 | c.5101G>A p.D1701N (on ENST00000396087 / NM_001244963.2; = p.D1645N on NM_145117.5) | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as COSV60663292; called by muse, mutect2, varscan2
- NAV3 | c.3509C>G p.S1170C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV57102434; called by muse, mutect2, varscan2
- NGLY1 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54989494; called by muse, mutect2
- NKG7 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV52467973; called by muse, mutect2, varscan2
- NRIP3 | c.198G>T p.R66S | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as rs780967687, COSV58470835; called by muse, mutect2, varscan2
- NRIP3 | c.197G>T p.R66M | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV58470850; called by muse, mutect2, varscan2
- NTNG1 | c.1471G>T p.A491S (on ENST00000370068 / NM_001113226.3; = p.A390S on NM_014917.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs746383416, COSV100903503, COSV64276985; called by muse, mutect2, varscan2
- OBSCN | c.16060G>A p.D5354N | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV99482212; called by muse, mutect2
- OR13C5 | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.344); catalogued as COSV66165168; called by muse, mutect2, varscan2
- OR4C13 | c.726C>G p.I242M | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.724); catalogued as rs1555015889, COSV73648865; called by muse, mutect2, varscan2
- OSBPL9 | c.1850C>G p.S617C | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV104401516, COSV61407263; called by muse, mutect2, varscan2
- OTOF | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.272); catalogued as rs747492513, COSV55514081; called by muse, mutect2, varscan2
- PAPPA2 | c.1505C>T p.T502I | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62783594; called by muse, mutect2
- PARP14 | c.4555C>T p.R1519* | Nonsense Mutation (SNP) | VAF 56/349 reads (16%) | catalogued as rs776658320, COSV71734877; called by muse, mutect2, varscan2
- PCDHB14 | c.359A>G p.E120G | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV53390373; called by muse, mutect2, varscan2
- PCSK2 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV52740015; called by muse, mutect2, varscan2
- PDE11A | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53704113; called by muse, mutect2, varscan2
- PDIA6 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1362415992, COSV55352596; called by muse, mutect2, varscan2
- PEAK1 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV56940901; called by muse, mutect2
- PHKA1 | c.2101T>G p.S701A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV59809471; called by muse, mutect2, varscan2
- PKNOX1 | c.106G>C p.D36H | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as COSV52338715; called by muse, mutect2, varscan2
- POLE | c.933G>C p.E311D | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.722); catalogued as COSV57687038; called by muse, mutect2, varscan2
- POU4F3 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57944583; called by muse, mutect2, varscan2
- PRAME | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.162); catalogued as COSV67162294; called by muse, mutect2, varscan2
- PSG1 | c.430+1G>A p.X144_splice | Splice Site (SNP) | VAF 148/386 reads (38%) | catalogued as rs375340094; called by muse, mutect2, varscan2
- PTPRT | c.2884+1G>A p.X962_splice | Splice Site (SNP) | VAF 60/193 reads (31%) | catalogued as COSV100623909, COSV61965711; called by muse, mutect2, varscan2
- PTPRZ1 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.125); catalogued as rs1469276203, COSV66432630; called by muse, mutect2, varscan2
- RAB3A | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55853506; called by muse, mutect2, varscan2
- RAE1 | c.757G>C p.D253H | Missense Mutation (SNP) | VAF 76/261 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV64798703; called by muse, mutect2, varscan2
- RASA2 | c.1973T>A p.L658H | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV53944298; called by muse, mutect2, varscan2
- RB1 | c.1786C>G p.L596V | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV57319930; called by muse, varscan2
- RIC1 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs199560727, COSV52613611; called by muse, mutect2, varscan2
- RILPL1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs947813611, COSV61553462; called by muse, mutect2, varscan2
- SCTR | c.399G>C p.E133D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV50030379; called by muse, mutect2, varscan2
- SEMA4C | c.266G>T p.W89L | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59691866; called by muse, mutect2
- SENP1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1239495661, COSV50301479; called by muse, mutect2, varscan2
- SERINC3 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as COSV54857931; called by muse, mutect2, varscan2
- SERPINB11 | c.84C>G p.I28M | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV66957595; called by muse, mutect2, varscan2
- SERPINI2 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.976); catalogued as COSV52985222; called by muse, mutect2, varscan2
- SETD6 | c.1236G>C p.W412C (on ENST00000219315 / NM_001160305.4; = p.W388C on NM_024860.3) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.482); catalogued as COSV54701051; called by muse, mutect2, varscan2
- SHPRH | c.2658G>C p.K886N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.409); catalogued as COSV51615301; called by muse, mutect2, varscan2
- SIPA1L3 | c.4380G>C p.K1460N | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV55921417; called by muse, mutect2, varscan2
- SLC2A3 | c.951C>G p.I317M | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV50005824; called by muse, mutect2
- SMC1A | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.314); catalogued as COSV59131197; called by muse, mutect2, varscan2
- SMPD4 | c.1919C>G p.A640G (on ENST00000409031 / NM_017951.4; = p.A611G on NM_017751.4) | Missense Mutation (SNP) | VAF 244/416 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60082026; called by muse, mutect2, varscan2
- SNX20 | c.250C>G p.R84G | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56057145, COSV56058408; called by muse, mutect2, varscan2
- SPIDR | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as COSV52386179; called by muse, mutect2, varscan2
- SSUH2 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV58032485; called by muse, mutect2, varscan2
- STK31 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV100669728, COSV63458515; called by muse, mutect2, varscan2
- STRC | c.482G>A p.C161Y | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70835582; called by muse, mutect2, varscan2
- SVIL | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as rs928334180, COSV63446628; called by muse, varscan2
- SVIL | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV63446633; called by muse, varscan2
- SYF2 | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs749059576, COSV52573632; called by muse, mutect2, varscan2
- SYT6 | c.1365-1G>C p.X455_splice (on ENST00000610222 / NM_001366225.1; = p.X370_splice on NM_205848.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 19/105 reads (18%) | catalogued as COSV65772258, COSV65774843, COSV65776573; called by muse, mutect2, varscan2
- TAAR9 | c.903T>A p.Y301* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV71512176; called by muse, mutect2, varscan2
- TAF1L | c.3079C>T p.R1027C | Missense Mutation (SNP) | VAF 49/373 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778201054, COSV54261755; called by muse, mutect2, varscan2
- TEX14 | c.2724G>C p.M908I (on ENST00000240361 / NM_001201457.2; = p.M902I on NM_031272.5) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV53623650; called by muse, mutect2, varscan2
- THRSP | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as rs370364182; called by muse, mutect2, varscan2
- TIMMDC1 | c.449+1G>A p.X150_splice | Splice Site (SNP) | VAF 8/21 reads (38%) | catalogued as COSV51787601; called by muse, mutect2, varscan2
- TLE1 | c.859C>G p.P287A | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.265); catalogued as COSV64691431; called by muse, mutect2, varscan2
- TMCO1 | c.264G>C p.K88N (on ENST00000612311 / NM_001256164.1; = p.K37N on NM_019026.6) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as COSV63318862; called by muse, mutect2, varscan2
- TMEM130 | c.963C>G p.I321M | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as COSV59560621; called by muse, mutect2
- TMEM132B | c.193A>G p.S65G | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54764075; called by muse, mutect2, varscan2
- TMEM87B | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51717492; called by muse, mutect2, varscan2
- TMTC3 | c.1565G>A p.R522K | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV57125602; called by muse, mutect2, varscan2
- TNS1 | c.3535C>G p.Q1179E | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.036); catalogued as COSV50721124, COSV50744264; called by muse, mutect2, varscan2
- TRIO | c.3620G>C p.C1207S | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV60091186; called by muse, mutect2, varscan2
- TRPM4 | c.1014C>G p.F338L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.025); catalogued as COSV53267032; called by muse, mutect2, varscan2
- TRPM6 | c.4685C>G p.S1562C | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.436); catalogued as COSV62519285; called by muse, mutect2, varscan2
- TSPAN15 | c.675C>G p.I225M | Missense Mutation (SNP) | VAF 123/214 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs778997740, COSV64783761; called by muse, mutect2, varscan2
- TTN | c.21065C>T p.S7022L (on ENST00000591111; = p.S6095L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | PolyPhen benign (0.035); catalogued as rs72648966, COSV60250210; called by muse, mutect2, varscan2
- TTN | c.11803C>G p.L3935V (on ENST00000591111; = p.L3889V on NM_003319.4) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV60250223; called by muse, mutect2, varscan2
- TUT4 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.347); catalogued as COSV57110642; called by muse, mutect2, varscan2
- TXNDC16 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV55986298; called by muse, mutect2, varscan2
- UQCRC2 | c.998C>G p.S333C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51673532; called by muse, mutect2, varscan2
- VGF | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.08); catalogued as rs1020444087, COSV99972819; called by muse, mutect2, varscan2
- VIT | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV64897418; called by muse, mutect2, varscan2
- WDR3 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.494); catalogued as rs962668739, COSV60464874; called by muse, mutect2, varscan2
- XRCC1 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV53451321, COSV53451859; called by muse, mutect2, varscan2
- YTHDC2 | c.3301A>G p.N1101D | Missense Mutation (SNP) | VAF 76/262 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV50749716; called by muse, mutect2, varscan2
- ZIK1 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56738094; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as rs1157700392, COSV58744080; called by muse, mutect2, varscan2
- ZMYM4 | c.3304C>T p.P1102S | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.778); catalogued as COSV100110986, COSV58915173; called by muse, mutect2, varscan2
- ZNF100 | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV59749295; called by muse, mutect2, varscan2
- ZNF12 | c.1930C>T p.R644W (on ENST00000405858 / NM_016265.4; = p.R606W on NM_006956.3) | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61245263; called by muse, mutect2, varscan2
- ZNF281 | c.1712G>A p.G571D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs1339294165, COSV54169050; called by muse, mutect2, varscan2
- ZNF287 | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV67688912; called by muse, mutect2, varscan2
- ZNF292 | c.8032A>G p.T2678A | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs1361874993, COSV60544528; called by muse, mutect2, varscan2
- ZNF382 | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV53091062; called by muse, mutect2
- ZNF572 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as COSV100074132, COSV60002117; called by muse, mutect2, varscan2
- ZNF572 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs754241764, COSV60002550; called by muse, mutect2, varscan2
- ZNF572 | c.1195C>G p.L399V | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60002557; called by muse, mutect2, varscan2
- ANK2 | c.5554G>T p.E1852* | Nonsense Mutation (SNP) | VAF 53/209 reads (25%) | called by muse, varscan2
- ANKRD11 | c.1223C>G p.S408* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- ARHGAP32 | c.3634C>T p.Q1212* (on ENST00000310343 / NM_001378025.1; = p.Q863* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- CEP126 | c.3094G>T p.E1032* | Nonsense Mutation (SNP) | VAF 69/250 reads (28%) | called by muse, mutect2, varscan2
- DMRT2 | c.1681C>T p.Q561* | Nonsense Mutation (SNP) | VAF 21/149 reads (14%) | called by muse, mutect2, varscan2
- DNAH11 | c.5512G>T p.E1838* | Nonsense Mutation (SNP) | VAF 57/383 reads (15%) | called by muse, mutect2, varscan2
- FNDC1 | c.2150C>G p.S717* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- GUCY1A1 | c.1642C>T p.Q548* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- IGLV7-43 | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF26B | c.6325T>C p.*2109Qext*34 | Nonstop Mutation (SNP) | VAF 27/98 reads (28%) | called by muse, mutect2, varscan2
- KMT2A | c.7682_7685dup p.E2563Lfs*2 | Frame Shift Ins (INS) | VAF 22/68 reads (32%) | called by mutect2, pindel, varscan2
- MARK2 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- MED4 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 21/142 reads (15%) | called by muse, mutect2, varscan2
- MUC16 | c.5354C>A p.S1785* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | called by muse, mutect2, varscan2
- NFKBIA | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2
- OR2W3 | c.677T>G p.L226* | Nonsense Mutation (SNP) | VAF 43/172 reads (25%) | called by muse, mutect2, varscan2
- PAIP2 | c.153A>T p.L51F | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDHA11 | c.1061del p.L354Cfs*17 | Frame Shift Del (DEL) | VAF 33/102 reads (32%) | called by mutect2, pindel, varscan2
- PLAU | c.627_628del p.C209Wfs*19 | Frame Shift Del (DEL) | VAF 152/314 reads (48%) | called by pindel, varscan2
- RUSC1 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- SAFB2 | c.581C>A p.S194* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- SUPT6H | c.4987C>T p.Q1663* | Nonsense Mutation (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- UCHL5 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 29/152 reads (19%) | called by muse, mutect2, varscan2
- ACCS | c.519C>G p.L173= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV55459745; called by muse, mutect2, varscan2
- ACOX1 | c.237C>T p.I79= | Silent (SNP) | VAF 31/188 reads (16%) | catalogued as rs201703373, COSV53132518, COSV53135362; called by muse, mutect2, varscan2
- ACSS3 | c.333C>T p.N111= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs548439952, COSV54098151; called by muse, mutect2, varscan2
- ADAMTS20 | c.3666C>T p.S1222= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV67136804; called by muse, mutect2, varscan2
- ADAMTS9 | c.2283A>G p.T761= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as COSV55787416; called by muse, mutect2, varscan2
- ADCY4 | c.621C>A p.L207= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV53476765; called by muse, mutect2, varscan2
- ARAP1 | c.1662G>A p.G554= (on ENST00000393609 / NM_001040118.2; = p.G309= on NM_015242.4) | Silent (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- BBS7 | c.1176C>T p.A392= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV52658614; called by muse, mutect2, varscan2
- CKAP5 | c.4206C>T p.F1402= | Silent (SNP) | VAF 30/151 reads (20%) | catalogued as COSV56372170; called by muse, mutect2, varscan2
- COL1A2 | c.2592G>A p.Q864= | Silent (SNP) | VAF 15/124 reads (12%) | catalogued as rs1174883561, COSV51961940, COSV51963581; called by muse, mutect2
- CS | c.1095G>A p.L365= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as COSV57525570; called by muse, mutect2, varscan2
- CYP4F12 | c.873C>G p.A291= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as rs1026759274, COSV61175649; called by muse, mutect2, varscan2
- DNAH17 | c.2781G>T p.L927= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV67754093, COSV67759281; called by muse, mutect2, varscan2
- DNASE1L1 | c.561C>T p.C187= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as rs782120218, COSV50010894; called by muse, mutect2
- DOCK7 | c.3927C>T p.L1309= (on ENST00000635253 / NM_001367561.1; = p.L1278= on NM_033407.3) | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV52016562; called by muse, mutect2, varscan2
- DONSON | c.1452G>A p.L484= | Silent (SNP) | VAF 27/176 reads (15%) | catalogued as rs751836395, COSV51667073; called by muse, mutect2, varscan2
- DSCAML1 | c.1296C>A p.L432= (on ENST00000321322; = p.L372= on NM_020693.4) | Silent (SNP) | VAF 51/199 reads (26%) | catalogued as COSV58399194; called by muse, mutect2, varscan2
- EDC4 | c.1230C>G p.L410= | Silent (SNP) | VAF 46/355 reads (13%) | catalogued as COSV62767368; called by muse, mutect2, varscan2
- EPHB3 | c.2196C>T p.V732= | Silent (SNP) | VAF 29/233 reads (12%) | catalogued as rs375412687; called by muse, mutect2, varscan2
- ETFB | c.231C>T p.T77= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as rs147509776; called by muse, mutect2
- EXOC3 | c.681T>A p.L227= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as COSV59268154; called by muse, mutect2, varscan2
- FAM13A | c.2500C>T p.L834= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as COSV52010027; called by muse, mutect2, varscan2
- FANCD2 | c.1596C>G p.L532= | Silent (SNP) | VAF 16/151 reads (11%) | catalogued as COSV55043951; called by muse, mutect2, varscan2
- FAT3 | c.12831G>A p.R4277= | Silent (SNP) | VAF 33/148 reads (22%) | catalogued as COSV53096231; called by muse, varscan2
- FCMR | c.60C>T p.L20= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as rs201853972, COSV65568861; called by muse, mutect2, varscan2
- FHDC1 | c.1326G>A p.L442= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV52602131; called by muse, mutect2, varscan2
- GON4L | c.897C>T p.I299= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV55200165; called by muse, mutect2, varscan2
- GRAMD4 | c.1680C>T p.T560= | Silent (SNP) | VAF 22/135 reads (16%) | catalogued as COSV63031857; called by muse, mutect2, varscan2
- GRID1 | c.1551C>A p.I517= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV60045268; called by muse, mutect2, varscan2
- GRIFIN | c.276G>A p.E92= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV70219134; called by muse, varscan2
- HOXD3 | c.393C>A p.P131= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV50883954; called by muse, mutect2, varscan2
- IGSF9B | c.399C>T p.L133= | Silent (SNP) | VAF 8/36 reads (22%) | called by mutect2, varscan2
- JMJD7 | c.858C>T p.I286= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs778454919, COSV59823180; called by muse, mutect2
- KCNH4 | c.1104C>T p.V368= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs768719248, COSV52920222; called by muse, mutect2
- KIF4B | c.1842G>A p.K614= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as COSV70530783, COSV70531898; called by muse, mutect2, varscan2
- LINGO2 | c.319C>T p.L107= | Silent (SNP) | VAF 88/214 reads (41%) | catalogued as COSV58062708; called by muse, mutect2, varscan2
- LRRC8E | c.1974C>G p.L658= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV60718906; called by muse, mutect2, varscan2
- METTL7A | c.210G>A p.G70= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV59841153; called by muse, mutect2, varscan2
- METTL7A | c.321G>A p.L107= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV59841160; called by muse, mutect2, varscan2
- MFSD3 | c.858G>T p.V286= | Silent (SNP) | VAF 48/284 reads (17%) | catalogued as COSV56742548; called by muse, mutect2, varscan2
- MUC16 | c.3156G>A p.L1052= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV67483332; called by muse, mutect2, varscan2
- MYOG | c.168G>T p.G56= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs1421842861, COSV54095277, COSV54096354; called by muse, mutect2, varscan2
- NFASC | c.3513G>A p.L1171= (on ENST00000339876 / NM_001378329.1; = p.L1100= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/262 reads (26%) | catalogued as COSV58375104; called by muse, mutect2, varscan2
- NOTUM | c.1206G>A p.V402= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV68826503; called by muse, mutect2
- OGDH | c.1590C>T p.I530= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as COSV56054907; called by muse, mutect2, varscan2
- OPTC | c.136C>T p.L46= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV58117082; called by muse, mutect2, varscan2
- PCDHA8 | c.1866C>T p.F622= | Silent (SNP) | VAF 56/186 reads (30%) | catalogued as rs782076274, COSV65330959; called by muse, mutect2, varscan2
- PIGV | c.1275G>A p.E425= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV50299243; called by muse, mutect2, varscan2
- PKP4 | c.840C>T p.A280= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV67678663; called by muse, mutect2, varscan2
- PLEC | c.12477C>A p.L4159= (on ENST00000322810 / NM_201380.4; = p.L4049= on NM_000445.5) | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV59676573; called by muse, mutect2, varscan2
- PRR11 | c.984G>A p.V328= | Silent (SNP) | VAF 24/170 reads (14%) | catalogued as rs573895797, COSV51877653; called by muse, mutect2, varscan2
- PSG2 | c.946T>C p.L316= | Silent (SNP) | VAF 44/349 reads (13%) | catalogued as COSV61545588, COSV61546038; called by muse, mutect2
- RFX1 | c.1683G>A p.T561= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs150138140; called by muse, mutect2, varscan2
- SEMA6D | c.114A>T p.S38= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV60381780; called by muse, varscan2
- SKAP1 | c.861C>T p.G287= | Silent (SNP) | VAF 9/257 reads (4%) | catalogued as rs1000468618, COSV61150393; called by muse, mutect2
- SORCS3 | c.879C>T p.L293= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV63819753; called by muse, mutect2, varscan2
- SRPX | c.936C>T p.G312= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- TFAP2A | c.669C>T p.L223= (on ENST00000482890; = p.L215= on NM_001032280.3) | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV60236601, COSV60236743; called by muse, mutect2, varscan2
- TNPO2 | c.309C>T p.L103= | Silent (SNP) | VAF 36/199 reads (18%) | catalogued as COSV63509547; called by muse, mutect2, varscan2
- TPTE | c.430C>A p.R144= (on ENST00000618007 / NM_199261.4; = p.R126= on NM_199259.4) | Silent (SNP) | VAF 19/176 reads (11%) | called by muse, mutect2, varscan2
- UMODL1 | c.342C>T p.F114= | Silent (SNP) | VAF 86/316 reads (27%) | catalogued as COSV68557207; called by muse, mutect2, varscan2
- USP51 | c.1086G>C p.L362= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV72351865; called by muse, mutect2, varscan2
- VPS13A | c.3282C>T p.N1094= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs372019796; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- WDR3 | c.2262G>A p.V754= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs1481605230, COSV60464870; called by muse, mutect2, varscan2
- WTIP | c.804G>C p.V268= | Silent (SNP) | VAF 28/198 reads (14%) | catalogued as rs759058007, COSV54329893; called by muse, mutect2, varscan2
- ZNF740 | c.189G>A p.R63= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV57244327; called by muse, mutect2, varscan2
- AKAP13 | c.4800-2158C>G | Intron (SNP) | VAF 85/239 reads (36%) | catalogued as rs763908818, COSV63465850; called by muse, mutect2, varscan2
- C3P1 | n.2430C>T | RNA (SNP) | VAF 27/201 reads (13%) | catalogued as rs1342023317; called by muse, mutect2, varscan2
- EIF4A2 | c.771+140G>A | Intron (SNP) | VAF 20/75 reads (27%) | catalogued as COSV99961293; called by muse, mutect2, varscan2
- XIRP2 | c.*483G>C | 3'UTR (SNP) | VAF 13/124 reads (10%) | catalogued as COSV54723832; called by muse, mutect2, varscan2
